Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016447-09A.3 (aliquot TARGET-15-SJMPAL016447-09A.3-01D) from TARGET case TARGET-15-SJMPAL016447, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,285 days).
Specimen TARGET-15-SJMPAL016447-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bca4628-a99a-4d72-a552-15465cd280bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016447-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016447-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/094adc1e-f3dc-471e-81cd-ecd5136314b5

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Intron 2, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 42/126 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- ARHGEF10 | c.1057G>A p.A353T (on ENST00000398564; = p.A328T on NM_014629.4) | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs977083004, COSV50643604; called by muse, mutect2, varscan2
- CEP192 | c.4442C>A p.A1481D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58068992; called by muse, mutect2, varscan2
- COL26A1 | c.886G>A p.V296M (on ENST00000313669 / NM_001278563.3; = p.V294M on NM_133457.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs768037612; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2
- KCNA4 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV60251905; called by muse, mutect2, varscan2
- NOTCH1 | c.7312_7313dup p.S2439Rfs*39 | Frame Shift Ins (INS) | VAF 27/76 reads (36%) | catalogued as COSV53047255, COSV53052980, COSV53102645; called by mutect2, pindel, varscan2
- NXN | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs370296358; called by mutect2, varscan2
- OR1S2 | c.616A>T p.M206L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs775290144, COSV56918768; called by muse, mutect2
- PPP3CA | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59919482; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | called by mutect2, pindel
- CFAP43 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FADS3 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PCDH9 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHKA1 | c.2666G>C p.S889T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RNF111 | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- SPTA1 | c.3714+2T>C p.X1238_splice | Splice Site (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- TTN | c.54059G>T p.G18020V (on ENST00000591111; = p.G10596V on NM_003319.4) | Missense Mutation (SNP) | VAF 159/373 reads (43%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG2 | c.1872C>A p.L624= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs1321243877; called by muse, varscan2
- POLR3C | c.696G>C p.G232= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- G3BP1 | c.351+1001C>T | Intron (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- GTSF1 | c.118-11dup | Intron (INS) | VAF 79/166 reads (48%) | called by mutect2, pindel, varscan2
